Somatic mutation profile of tumor specimen 0DMWTU from CCDI case PBCAMV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.8 years (3,954 days).
Specimen 0DMWTU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2907a47-6388-4d1b-a545-d495046c432b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMWTZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/459b632d-8586-448b-aaf8-d7e20bf456ef

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL645922.1 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 28/588 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV54960409; called by muse, mutect2
- CENPK | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 170/479 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99669565; called by muse, mutect2, varscan2
- FFAR1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 167/435 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.397); catalogued as rs778277031, COSV50070531; called by muse, mutect2, varscan2
- BEND7 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 113/307 reads (37%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TSPEAR | c.108G>A p.A36= | Silent (SNP) | VAF 187/480 reads (39%) | catalogued as rs782589581, COSV59961184; called by muse, mutect2, varscan2
- CACHD1 | c.2095-50T>C | Intron (SNP) | VAF 64/130 reads (49%) | called by mutect2, varscan2
- P2RX3 | c.485+35C>G | Intron (SNP) | VAF 128/284 reads (45%) | catalogued as rs541753717; called by muse, mutect2, varscan2
